TARGET case TARGET-00-RO02748 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/072c5e82-3b17-4fba-842f-a9f73591c55d

Biospecimens (1 sample)
- Sample TARGET-00-RO02748-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
